Somatic mutation profile of tumor specimen C3L-02857-01 (aliquot CPT0203410006) from CPTAC case C3L-02857, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.6 years (24,330 days).
Specimen C3L-02857-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec933961-6b32-4fe9-98e6-3e125896730b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02857-31 (Blood Derived Normal), aliquot CPT0204060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b67afe88-9210-4819-9501-f12cfc9c98f6

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Intron 3, Nonsense Mutation 2, 3'Flank 1, Splice Site 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.7280T>A p.L2427Q | Missense Mutation (SNP) | VAF 47/193 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1085307113, COSV63869220, COSV63869886, COSV63874900; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EMC10 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 63/373 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs779598164; called by muse, mutect2, varscan2
- PCDHA2 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 41/1148 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554119963, COSV65369813; called by muse, mutect2
- PCDHA9 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 213/1126 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.329); catalogued as COSV65331504; called by muse, mutect2, varscan2
- RETREG1 | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 27/549 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1477910110; called by muse, mutect2
- ROS1 | c.3494T>A p.V1165D | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV63855559; called by muse, mutect2, varscan2
- SPOCD1 | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99929462; called by muse, mutect2, varscan2
- TEAD2 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 73/351 reads (21%) | catalogued as rs530263544, COSV60872933; called by muse, mutect2, varscan2
- TMEM26 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 22/777 reads (3%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs1017279780, COSV53262420; called by muse, mutect2
- CACNA1B | c.3752G>T p.R1251I | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- CNNM4 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 92/449 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EXD3 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAM240C | c.273C>A p.D91E | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- FAT3 | c.9527G>A p.G3176E | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2
- HGD | c.386A>T p.N129I | Missense Mutation (SNP) | VAF 130/589 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- HNF4G | c.1052G>T p.G351V (on ENST00000354370 / NM_001330561.2; = p.G398V on NM_004133.5) | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- IFIT5 | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- IMMT | c.209A>G p.H70R | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- INTS8 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- NFKBIL1 | c.848A>T p.E283V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R13B | c.1808A>T p.K603M | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PRRC2B | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 111/499 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SACS | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 68/386 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SH2D4A | c.1131G>T p.R377S | Missense Mutation (SNP) | VAF 56/660 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2
- STAB1 | c.5176-2A>G p.X1726_splice | Splice Site (SNP) | VAF 27/286 reads (9%) | called by muse, mutect2
- CCDC110 | c.534T>C p.N178= | Silent (SNP) | VAF 39/163 reads (24%) | called by muse, mutect2, varscan2
- ITFG2 | c.42C>T p.F14= | Silent (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- PRSS33 | c.711C>T p.C237= | Silent (SNP) | VAF 46/179 reads (26%) | catalogued as rs1287693695; called by muse, mutect2, varscan2
- PTPRCAP | c.531G>A p.L177= | Silent (SNP) | VAF 57/284 reads (20%) | called by muse, mutect2, varscan2
- RHPN2 | c.1752C>T p.D584= | Silent (SNP) | VAF 22/451 reads (5%) | catalogued as rs777884423; called by muse, mutect2
- SULT1A2 | c.783T>A p.A261= | Silent (SNP) | VAF 42/698 reads (6%) | called by muse, mutect2
- VMP1 | c.1149C>T p.I383= | Silent (SNP) | VAF 44/212 reads (21%) | called by muse, mutect2, varscan2
- ZNF469 | c.4200G>A p.Q1400= (on ENST00000437464; = p.Q1428= on NM_001367624.2) | Silent (SNP) | VAF 44/356 reads (12%) | called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1534G>C | RNA (SNP) | VAF 9/118 reads (8%) | catalogued as rs902384255, COSV67268443; called by muse, mutect2
- CSNK1E | c.*32+44A>G | Intron (SNP) | VAF 78/341 reads (23%) | called by muse, mutect2, varscan2
- ESPN | chr1:6460071 G>A | 3'Flank (SNP) | VAF 11/291 reads (4%) | called by muse, mutect2
- LRRC72 | c.164+146_164+147del | Intron (DEL) | VAF 28/180 reads (16%) | called by pindel, varscan2
- STXBP2 | c.1107+17G>T | Intron (SNP) | VAF 50/219 reads (23%) | called by muse, mutect2, varscan2
- VNN3 | c.*201T>G | 3'UTR (SNP) | VAF 38/225 reads (17%) | called by muse, mutect2, varscan2
